MMRF case MMRF_2223 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f347042c-6f4e-4277-973b-34f53bdc8e91

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.1 years (29,974 days); ISS stage: I; Days to last known disease status: 897 days (2.5 years); Days to last follow up: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 447 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 1.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 24.3 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 8.1 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.004 mg/dL.
- Day 64 (ECOG 0): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 176 (ECOG 0): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 3.81 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 4.68 mmol/L.
- Day 265 (ECOG 1): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 6.66 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 349 (ECOG 0): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 7.98 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.35 mmol/L.
- Day 433 (ECOG 2): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 9.39 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.01 mmol/L.
- Day 517 (ECOG 1): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 8.97 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 657 (ECOG 1): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.
- Day 713 (ECOG 1): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 769 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 9.81 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 897 (ECOG 1): M Protein 0.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 9.96 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 4.29 mmol/L.

Other clinical attributes
- Day -13: Weight: 55 kg; Height: 151 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2223_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2223_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
